Somatic mutation profile of tumor specimen ALCH-AE0S-TTP1-A (aliquot ALCH-AE0S-TTP1-A-1-0-D-A582-36) from ALCHEMIST case ALCH-AE0S, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 71.7 years (26,184 days).
Specimen ALCH-AE0S-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cac55eda-13cf-4ab6-a6b0-2b1fb9edb2c7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AE0S-NB1-A (Blood Derived Normal), aliquot ALCH-AE0S-NB1-A-2-0-D-A582-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/aa913260-c309-47e3-866a-b0c3d5a2c3de

The open-access MAF lists 322 somatic variants for this specimen: 210 protein-altering or splice-affecting, 78 silent, 34 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 171, Silent 78, Nonsense Mutation 15, RNA 9, Intron 9, Frame Shift Del 8, 3'UTR 6, Splice Region 6, Splice Site 5, 5'UTR 5, 5'Flank 4, Frame Shift Ins 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PRRT2 | c.1011C>T p.G337= | Splice Region (SNP) | VAF 76/172 reads (44%) | catalogued as rs745970212, CD120159, CS1210624, COSV54886687; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.747G>T p.R249S | Missense Mutation (SNP) | VAF 443/614 reads (72%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs28934571, COSV52661594, COSV52668882, COSV52827572; ClinVar: pathogenic / likely pathogenic / conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- ADAMTS12 | c.1262G>T p.R421L | Missense Mutation (SNP) | VAF 91/333 reads (27%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.564); catalogued as COSV61263538; called by muse, mutect2, varscan2
- AFF3 | c.2936A>G p.Y979C | Missense Mutation (SNP) | VAF 79/218 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1206689082; called by muse, mutect2, varscan2
- AMELX | c.337C>A p.Q113K | Missense Mutation (SNP) | VAF 52/1444 reads (4%) | SIFT tolerated (0.45); PolyPhen benign (0.321); catalogued as COSV61634504; called by muse, mutect2
- ARHGEF17 | c.5234C>G p.T1745S | Missense Mutation (SNP) | VAF 81/301 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1412295435; called by muse, mutect2, varscan2
- ATG2A | c.3997C>T p.P1333S | Missense Mutation (SNP) | VAF 83/810 reads (10%) | SIFT tolerated (0.57); PolyPhen benign (0.005); catalogued as rs757206028; called by muse, mutect2, varscan2
- BRK1 | c.58G>T p.E20* | Nonsense Mutation (SNP) | VAF 87/754 reads (12%) | catalogued as rs1326668345, COSV99845249; called by muse, mutect2, varscan2
- CAMSAP1 | c.2983G>A p.E995K | Missense Mutation (SNP) | VAF 204/322 reads (63%) | SIFT tolerated (0.12); PolyPhen benign (0.23); catalogued as rs571335059; called by muse, mutect2, varscan2
- CCDC15 | c.128G>C p.G43A | Missense Mutation (SNP) | VAF 116/584 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1248843282; called by muse, mutect2, varscan2
- CCDC175 | c.1717A>G p.K573E | Missense Mutation (SNP) | VAF 51/109 reads (47%) | SIFT tolerated (0.96); PolyPhen benign (0.018); catalogued as rs1443377820; called by muse, mutect2, varscan2
- CDC14C | c.808G>A p.G270S (on ENST00000428251; = p.G163S on NM_152627.3) | Missense Mutation (SNP) | VAF 254/712 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.296); catalogued as rs763976791; called by muse, mutect2
- CDH18 | c.1743C>A p.S581R | Missense Mutation (SNP) | VAF 156/361 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.471); catalogued as COSV56941921; called by muse, mutect2, varscan2
- CENPJ | c.1582C>T p.L528F | Missense Mutation (SNP) | VAF 49/81 reads (60%) | SIFT tolerated (0.1); PolyPhen benign (0.018); catalogued as rs773921055; called by muse, mutect2, varscan2
- CHD4 | c.3727C>T p.R1243W (on ENST00000357008 / NM_001363606.2; = p.R1256W on NM_001273.5) | Missense Mutation (SNP) | VAF 150/390 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1371509409, COSV100538137; called by muse, mutect2, varscan2
- CHRNB2 | c.1103G>T p.R368L | Missense Mutation (SNP) | VAF 683/1465 reads (47%) | SIFT tolerated (0.6); PolyPhen benign (0.015); catalogued as rs202114705; called by muse, mutect2, varscan2
- CRYBG2 | c.1696G>A p.V566M | Missense Mutation (SNP) | VAF 343/524 reads (65%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.987); catalogued as rs1429909695; called by muse, mutect2, varscan2
- CSMD1 | c.5748C>A p.C1916* (on ENST00000520002; = p.C1915* on NM_033225.6) | Nonsense Mutation (SNP) | VAF 122/187 reads (65%) | catalogued as COSV100148279; called by muse, mutect2, varscan2
- CT47B1 | c.607C>A p.P203T | Missense Mutation (SNP) | VAF 782/1620 reads (48%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.685); catalogued as COSV64891057; called by muse, mutect2, varscan2
- CT47B1 | c.461G>A p.G154E | Missense Mutation (SNP) | VAF 381/896 reads (43%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.998); catalogued as COSV64891013; called by muse, mutect2, varscan2
- DLGAP3 | c.493G>T p.E165* | Nonsense Mutation (SNP) | VAF 563/735 reads (77%) | catalogued as COSV52393713, COSV52396045; called by muse, mutect2, varscan2
- F5 | c.3687G>T p.M1229I | Missense Mutation (SNP) | VAF 114/349 reads (33%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs878968922; called by muse, mutect2, varscan2
- FLNA | c.3557C>G p.S1186W | Missense Mutation (SNP) | VAF 113/444 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as CM030671, COSV61038381; called by muse, mutect2, varscan2
- FRMPD3 | c.865C>T p.R289W | Missense Mutation (SNP) | VAF 28/142 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV52193197; called by muse, varscan2
- GRIN1 | c.1752C>T p.S584= | Splice Region (SNP) | VAF 133/286 reads (47%) | catalogued as rs753854462, COSV59292596; called by muse, varscan2
- HOXB8 | c.212A>G p.Q71R | Missense Mutation (SNP) | VAF 97/628 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV99494069; called by muse, mutect2, varscan2
- IGLV1-36 | c.146G>C p.G49A | Missense Mutation (SNP) | VAF 112/726 reads (15%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.11); catalogued as rs1218146180; called by muse, mutect2, varscan2
- IL1RAP | c.1174C>T p.H392Y | Missense Mutation (SNP) | VAF 70/1180 reads (6%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.603); catalogued as rs745608321; called by muse, mutect2
- IPMK | c.304G>T p.V102F | Missense Mutation (SNP) | VAF 73/125 reads (58%) | SIFT tolerated (0.29); PolyPhen benign (0.143); catalogued as rs1305794759; called by muse, mutect2, varscan2
- ITIH1 | c.117G>T p.E39D | Missense Mutation (SNP) | VAF 49/69 reads (71%) | SIFT tolerated (0.24); PolyPhen benign (0.055); catalogued as COSV99834923; called by muse, mutect2, varscan2
- KCND2 | c.708C>A p.C236* | Nonsense Mutation (SNP) | VAF 205/936 reads (22%) | catalogued as COSV58570515; called by muse, mutect2, varscan2
- KIF5A | c.2512G>C p.E838Q | Missense Mutation (SNP) | VAF 95/957 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.311); catalogued as COSV54052551; called by muse, mutect2
- KIFC2 | c.2336C>T p.P779L | Missense Mutation (SNP) | VAF 112/364 reads (31%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0); catalogued as rs769546469; called by muse, mutect2, varscan2
- LINGO2 | c.331C>T p.R111C | Missense Mutation (SNP) | VAF 92/180 reads (51%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.932); catalogued as rs139845137; called by muse, mutect2, varscan2
- LRP1 | c.5867G>A p.R1956H | Missense Mutation (SNP) | VAF 314/935 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs200890734, COSV54505199; called by muse, mutect2, varscan2
- LRRC1 | c.185G>T p.R62L | Missense Mutation (SNP) | VAF 99/217 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV63823143; called by muse, mutect2, varscan2
- LRRC4C | c.1840A>T p.I614L | Missense Mutation (SNP) | VAF 10/262 reads (4%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV53439613; called by muse, mutect2
- LRRTM4 | c.1690G>T p.E564* | Nonsense Mutation (SNP) | VAF 406/1046 reads (39%) | catalogued as COSV101299409; called by mutect2, varscan2
- LTF | c.432G>T p.W144C | Missense Mutation (SNP) | VAF 98/344 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51606657; called by muse, mutect2, varscan2
- MLX | c.520G>A p.A174T | Missense Mutation (SNP) | VAF 302/454 reads (67%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.948); catalogued as rs1166401759, COSV53816431; called by muse, mutect2, varscan2
- MUC16 | c.25647G>A p.W8549* | Nonsense Mutation (SNP) | VAF 18/90 reads (20%) | catalogued as rs1462563864; called by muse, mutect2, varscan2
- MYH14 | c.517C>G p.H173D | Missense Mutation (SNP) | VAF 214/318 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51820327; called by muse, mutect2, varscan2
- MYH6 | c.2962G>T p.D988Y | Missense Mutation (SNP) | VAF 213/428 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV62448389; called by muse, mutect2, varscan2
- MYO10 | c.1781G>T p.R594L | Missense Mutation (SNP) | VAF 147/650 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.315); catalogued as COSV72563221; called by muse, mutect2, varscan2
- MYOM1 | c.145C>T p.R49C | Missense Mutation (SNP) | VAF 529/1059 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.446); catalogued as rs765572797; called by muse, mutect2, varscan2
- MYRF | c.286G>A p.G96S (on ENST00000278836 / NM_001127392.3; = p.G87S on NM_013279.4) | Missense Mutation (SNP) | VAF 157/381 reads (41%) | SIFT tolerated (0.4); PolyPhen benign (0.005); catalogued as rs761015382, COSV53890668; called by muse, mutect2, varscan2
- NDC1 | c.611G>A p.R204H | Missense Mutation (SNP) | VAF 37/280 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as rs202236360; called by muse, mutect2, varscan2
- NF1 | c.5273G>A p.G1758D (on ENST00000358273 / NM_001042492.3; = p.G1737D on NM_000267.3) | Missense Mutation (SNP) | VAF 149/575 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV62228087; called by muse, mutect2, varscan2
- NFATC2 | c.1585C>T p.R529W | Missense Mutation (SNP) | VAF 129/435 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1167540083, COSV65355005; called by muse, mutect2, varscan2
- OCM2 | c.146G>A p.R49Q | Missense Mutation (SNP) | VAF 32/476 reads (7%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as rs1045262559; called by muse, mutect2
- OR10T2 | c.722G>C p.C241S | Missense Mutation (SNP) | VAF 22/105 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100554821; called by muse, mutect2, varscan2
- OTC | c.908G>T p.C303F | Missense Mutation (SNP) | VAF 160/600 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as CM971112, COSV99234266; called by muse, mutect2, varscan2
- OTOG | c.8334C>A p.P2778= | Splice Region (SNP) | VAF 29/106 reads (27%) | catalogued as rs569159135, COSV100695230; ClinVar: likely benign; called by muse, mutect2, varscan2
- PCSK4 | c.1444C>A p.L482I | Missense Mutation (SNP) | VAF 12/216 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.047); catalogued as COSV56299805; called by muse, mutect2
- RECQL | c.502G>C p.E168Q | Missense Mutation (SNP) | VAF 34/129 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.653); catalogued as rs1291025783, COSV100131309; called by muse, mutect2, varscan2
- ROS1 | c.5312G>T p.W1771L | Missense Mutation (SNP) | VAF 39/258 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs199563442, COSV63851176; called by muse, mutect2, varscan2
- RPS6KA6 | c.1896G>T p.E632D | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as COSV99425099; called by muse, mutect2, varscan2
- SHOX2 | c.596A>G p.E199G (on ENST00000441443 / NM_006884.3; = p.E223G on NM_003030.4) | Missense Mutation (SNP) | VAF 46/110 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV67463483; called by muse, mutect2, varscan2
- SHROOM2 | c.1586C>A p.A529D | Missense Mutation (SNP) | VAF 40/777 reads (5%) | SIFT tolerated (0.46); PolyPhen benign (0.221); catalogued as COSV66610644; called by muse, mutect2
- SLC12A3 | c.1837G>T p.G613C | Missense Mutation (SNP) | VAF 55/1368 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM981830, COSV52636646; called by muse, mutect2
- SLC25A5 | c.463C>T p.R155* | Nonsense Mutation (SNP) | VAF 71/388 reads (18%) | catalogued as COSV100510530; called by muse, varscan2
- SLC6A1 | c.770G>A p.R257H | Missense Mutation (SNP) | VAF 148/411 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.908); catalogued as rs536009666; called by muse, mutect2, varscan2
- SOGA3 | c.2270C>T p.A757V | Missense Mutation (SNP) | VAF 36/206 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.357); catalogued as COSV64107655; called by muse, mutect2, varscan2
- SRGAP3 | c.1492G>T p.V498L | Missense Mutation (SNP) | VAF 270/1189 reads (23%) | SIFT tolerated (0.7); PolyPhen benign (0.005); catalogued as rs376476983; called by muse, mutect2, varscan2
- SSX7 | c.330+1G>T p.X110_splice | Splice Site (SNP) | VAF 82/313 reads (26%) | catalogued as rs1421757866; called by muse, mutect2, varscan2
- STAT5B | c.881G>A p.R294H | Missense Mutation (SNP) | VAF 393/738 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as rs754523154; called by muse, mutect2, varscan2
- TENM3 | c.5787C>A p.N1929K | Missense Mutation (SNP) | VAF 46/144 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.033); catalogued as COSV69309718; called by muse, varscan2
- TMEM208 | c.227G>A p.R76Q | Missense Mutation (SNP) | VAF 64/147 reads (44%) | SIFT tolerated (0.22); PolyPhen benign (0.058); catalogued as rs776135486; called by muse, mutect2, varscan2
- TOPORS | c.1872G>A p.M624I | Missense Mutation (SNP) | VAF 207/381 reads (54%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV62116179; called by muse, mutect2, varscan2
- TRPA1 | c.1980C>G p.F660L | Missense Mutation (SNP) | VAF 36/297 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV51568987, COSV51575764; called by muse, mutect2, varscan2
- TRPM2 | c.4304C>T p.T1435M | Missense Mutation (SNP) | VAF 158/688 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as rs140351977, COSV55978351; called by muse, mutect2, varscan2
- TRPM5 | c.2503C>T p.R835C | Missense Mutation (SNP) | VAF 198/449 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1435477356; called by muse, mutect2, varscan2
- TXNRD1 | c.215G>A p.S72N | Missense Mutation (SNP) | VAF 113/287 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.432); catalogued as rs772519302; called by muse, mutect2, varscan2
- UNC80 | c.497C>T p.S166F | Missense Mutation (SNP) | VAF 114/218 reads (52%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.116); catalogued as COSV55887775; called by muse, mutect2, varscan2
- ZBED8 | c.968G>C p.S323T | Missense Mutation (SNP) | VAF 18/234 reads (8%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as COSV68824432; called by muse, mutect2
- ZFP42 | c.659C>A p.A220E | Missense Mutation (SNP) | VAF 59/154 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.914); catalogued as COSV58817214; called by muse, mutect2, varscan2
- ZNF385D | c.524C>G p.S175C | Missense Mutation (SNP) | VAF 38/259 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV55758915; called by muse, varscan2
- ABCF1 | c.1160G>T p.R387L (on ENST00000326195 / NM_001025091.2; = p.R349L on NM_001090.3) | Missense Mutation (SNP) | VAF 179/396 reads (45%) | SIFT tolerated (0.52); PolyPhen benign (0.208); called by muse, mutect2, varscan2
- ADAMTS9 | c.3787G>A p.V1263M | Missense Mutation (SNP) | VAF 19/236 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- ADCYAP1 | c.14G>T p.S5I | Missense Mutation (SNP) | VAF 31/552 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); called by muse, mutect2
- AFF2 | c.1872G>T p.R624S | Missense Mutation (SNP) | VAF 46/186 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.572); called by mutect2, varscan2
- AFF3 | c.3230G>A p.R1077Q | Missense Mutation (SNP) | VAF 178/381 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- AKAP6 | c.4216G>A p.V1406I | Missense Mutation (SNP) | VAF 69/168 reads (41%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ALOX5 | c.228G>C p.W76C | Missense Mutation (SNP) | VAF 158/1300 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.779); called by muse, mutect2, varscan2
- ANKRD11 | c.6902C>T p.A2301V | Missense Mutation (SNP) | VAF 61/203 reads (30%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- AREG | c.667C>G p.L223V | Missense Mutation (SNP) | VAF 78/354 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.38); called by muse, mutect2, varscan2
- ARHGAP31 | c.3121G>C p.A1041P | Missense Mutation (SNP) | VAF 24/618 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.012); called by muse, mutect2
- ASCC3 | c.3502A>G p.I1168V | Missense Mutation (SNP) | VAF 303/727 reads (42%) | SIFT tolerated (0.58); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ATP2B4 | c.2406+2T>A p.X802_splice | Splice Site (SNP) | VAF 159/329 reads (48%) | called by muse, mutect2, varscan2
- BCL6B | c.794T>C p.F265S | Missense Mutation (SNP) | VAF 253/366 reads (69%) | SIFT tolerated (0.58); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- BTNL9 | c.208A>G p.M70V | Missense Mutation (SNP) | VAF 265/447 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- C5orf22 | c.940T>A p.L314M | Missense Mutation (SNP) | VAF 127/302 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- C8orf74 | c.574G>T p.E192* | Nonsense Mutation (SNP) | VAF 52/74 reads (70%) | called by muse, mutect2, varscan2
- CACNA2D1 | c.120G>T p.M40I | Missense Mutation (SNP) | VAF 218/559 reads (39%) | SIFT tolerated (0.49); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- CDC14C | c.809G>T p.G270V (on ENST00000428251; = p.G163V on NM_152627.3) | Missense Mutation (SNP) | VAF 257/717 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); called by muse, mutect2
- CDK19 | c.859A>T p.T287S | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT tolerated (0.22); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- CDT1 | c.88C>G p.P30A | Missense Mutation (SNP) | VAF 20/566 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.045); called by muse, mutect2
- CEP104 | c.156G>C p.E52D | Missense Mutation (SNP) | VAF 120/352 reads (34%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- CLEC4C | c.188A>G p.Q63R | Missense Mutation (SNP) | VAF 133/317 reads (42%) | SIFT tolerated (0.55); PolyPhen benign (0.302); called by muse, mutect2, varscan2
- CLSTN2 | c.480del p.F160Lfs*10 | Frame Shift Del (DEL) | VAF 189/638 reads (30%) | called by mutect2, pindel, varscan2
- CNST | c.62_72del p.P21Rfs*14 | Frame Shift Del (DEL) | VAF 46/274 reads (17%) | called by pindel, varscan2
- COL7A1 | c.5622G>C p.K1874N | Missense Mutation (SNP) | VAF 107/521 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- COQ9 | c.179A>G p.Q60R | Missense Mutation (SNP) | VAF 406/980 reads (41%) | SIFT tolerated (0.32); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- CPXCR1 | c.868G>T p.E290* | Nonsense Mutation (SNP) | VAF 10/26 reads (38%) | called by muse, varscan2
- CXCR5 | c.869T>C p.V290A | Missense Mutation (SNP) | VAF 104/514 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- DACH2 | c.1484G>A p.R495K | Missense Mutation (SNP) | VAF 55/331 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- DENND5B | c.1128T>A p.F376L | Missense Mutation (SNP) | VAF 52/105 reads (50%) | SIFT tolerated (0.66); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DNAH3 | c.2963T>C p.V988A | Missense Mutation (SNP) | VAF 41/202 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- DNAH3 | c.1742A>G p.E581G | Missense Mutation (SNP) | VAF 61/208 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- DNAH6 | c.3793G>T p.V1265F | Missense Mutation (SNP) | VAF 71/107 reads (66%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, varscan2
- DNAH9 | c.1472G>T p.R491M | Missense Mutation (SNP) | VAF 67/109 reads (61%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.537); called by muse, mutect2, varscan2
- DNASE1L1 | c.863T>C p.L288P | Missense Mutation (SNP) | VAF 54/386 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- DOCK1 | c.2255C>T p.S752F | Missense Mutation (SNP) | VAF 417/569 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- DVL1 | c.1834del p.V612Wfs*62 (on ENST00000378888 / NM_001330311.2; = p.V587Wfs*62 on NM_004421.3) | Frame Shift Del (DEL) | VAF 148/255 reads (58%) | called by mutect2, pindel, varscan2
- ECH1 | c.731+3A>G | Splice Region (SNP) | VAF 60/2153 reads (3%) | called by muse, mutect2
- ELK3 | c.174G>C p.K58N | Missense Mutation (SNP) | VAF 197/536 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- EPHA6 | c.3025_3027del p.K1009del | In Frame Del (DEL) | VAF 35/134 reads (26%) | called by mutect2, pindel, varscan2
- FANCC | c.456T>C p.N152= | Splice Region (SNP) | VAF 24/133 reads (18%) | called by muse, mutect2, varscan2
- FRMPD3 | c.472G>T p.E158* | Nonsense Mutation (SNP) | VAF 50/240 reads (21%) | called by muse, mutect2, varscan2
- GAB1 | c.218C>T p.T73I | Missense Mutation (SNP) | VAF 53/387 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.385); called by muse, mutect2, varscan2
- GLG1 | c.1478C>G p.P493R | Missense Mutation (SNP) | VAF 81/236 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.761); called by muse, mutect2, varscan2
- GOSR1 | c.206C>A p.T69K | Missense Mutation (SNP) | VAF 17/245 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.477); called by muse, mutect2
- HACD1 | c.728A>G p.N243S | Missense Mutation (SNP) | VAF 118/152 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HELZ2 | c.1486C>T p.P496S | Missense Mutation (SNP) | VAF 192/444 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HOXD13 | c.743A>G p.Q248R | Missense Mutation (SNP) | VAF 66/93 reads (71%) | SIFT deleterious (0); PolyPhen benign (0.418); called by muse, mutect2, varscan2
- HPS5 | c.1220A>T p.H407L (on ENST00000349215 / NM_181507.2; = p.H293L on NM_007216.4) | Missense Mutation (SNP) | VAF 379/891 reads (43%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2, varscan2
- HRG | c.391+1G>C p.X131_splice | Splice Site (SNP) | VAF 108/1068 reads (10%) | called by muse, mutect2
- HS3ST4 | c.699C>A p.F233L | Missense Mutation (SNP) | VAF 61/174 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.757); called by muse, mutect2, varscan2
- HSP90AB1 | c.1033G>C p.E345Q | Missense Mutation (SNP) | VAF 35/332 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- HTR3B | c.76C>T p.H26Y | Missense Mutation (SNP) | VAF 33/429 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.335); called by muse, mutect2
- IL12RB2 | c.1624A>C p.N542H | Missense Mutation (SNP) | VAF 196/484 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.579); called by muse, mutect2, varscan2
- ITGB2 | c.20dup p.L8Tfs*51 | Frame Shift Ins (INS) | VAF 205/896 reads (23%) | called by mutect2, pindel, varscan2
- JAG2 | c.2519_2520insGG p.T841Afs*26 | Frame Shift Ins (INS) | VAF 281/799 reads (35%) | called by mutect2, pindel, varscan2
- KAT2B | c.1498G>T p.G500C | Missense Mutation (SNP) | VAF 261/729 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- KCNK10 | c.1033del p.A345Pfs*81 | Frame Shift Del (DEL) | VAF 23/133 reads (17%) | called by mutect2, pindel
- KDM4D | c.1261G>A p.A421T | Missense Mutation (SNP) | VAF 320/927 reads (35%) | SIFT tolerated (0.3); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KIAA0232 | c.3338C>T p.A1113V | Missense Mutation (SNP) | VAF 131/221 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KLF11 | c.214C>G p.L72V | Missense Mutation (SNP) | VAF 159/591 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.847); called by muse, mutect2, varscan2
- KLRC1 | c.197C>T p.S66L | Missense Mutation (SNP) | VAF 84/229 reads (37%) | SIFT tolerated (0.33); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- KNL1 | c.4059G>C p.E1353D (on ENST00000346991 / NM_170589.5; = p.E1327D on NM_144508.5) | Missense Mutation (SNP) | VAF 16/174 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.024); called by muse, mutect2
- KRTAP20-3 | c.34_35dup p.Y13Afs*51 | Frame Shift Ins (INS) | VAF 40/162 reads (25%) | called by mutect2, pindel, varscan2
- LONRF3 | c.1112G>T p.G371V (on ENST00000371628 / NM_001031855.3; = p.G330V on NM_024778.5) | Missense Mutation (SNP) | VAF 36/216 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- LRP2 | c.11429G>A p.C3810Y | Missense Mutation (SNP) | VAF 249/439 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRRFIP2 | c.633A>T p.L211F | Missense Mutation (SNP) | VAF 66/192 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LY6G5C | c.265C>A p.R89S | Missense Mutation (SNP) | VAF 170/583 reads (29%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.412); called by muse, varscan2
- MAGEE2 | c.627G>C p.W209C | Missense Mutation (SNP) | VAF 93/565 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.273); called by muse, mutect2, varscan2
- MAMLD1 | c.1846C>A p.Q616K | Missense Mutation (SNP) | VAF 402/1856 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.288); called by muse, varscan2
- MAP2K2 | c.370G>T p.E124* | Nonsense Mutation (SNP) | VAF 259/389 reads (67%) | called by muse, mutect2, varscan2
- MAPK4 | c.1315G>T p.D439Y | Missense Mutation (SNP) | VAF 105/236 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- MMUT | c.1360G>T p.G454* | Nonsense Mutation (SNP) | VAF 97/395 reads (25%) | called by muse, mutect2, varscan2
- MS4A14 | c.550del p.L184Ffs*27 | Frame Shift Del (DEL) | VAF 42/157 reads (27%) | called by mutect2, pindel, varscan2
- MSN | c.142C>T p.Q48* | Nonsense Mutation (SNP) | VAF 227/469 reads (48%) | called by muse, mutect2, varscan2
- MUC17 | c.2442C>A p.S814R | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.351); called by muse, mutect2, varscan2
- MYO16 | c.2702C>G p.A901G | Missense Mutation (SNP) | VAF 20/374 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.532); called by muse, mutect2
- MYO5A | c.4708C>A p.Q1570K | Missense Mutation (SNP) | VAF 177/781 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NCAPD2 | c.639C>A p.H213Q | Missense Mutation (SNP) | VAF 60/488 reads (12%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- NHS | c.3826G>T p.D1276Y | Missense Mutation (SNP) | VAF 150/472 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.884); called by muse, mutect2, varscan2
- NLGN3 | c.480C>G p.C160W | Missense Mutation (SNP) | VAF 22/130 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.851); called by muse, varscan2
- OR2M5 | c.326G>C p.G109A | Missense Mutation (SNP) | VAF 60/308 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.899); called by muse, varscan2
- OR3A2 | c.268dup p.M90Nfs*15 | Frame Shift Ins (INS) | VAF 62/98 reads (63%) | called by mutect2, varscan2
- OTUD7A | c.212C>G p.T71R | Missense Mutation (SNP) | VAF 195/520 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PADI4 | c.458A>T p.N153I | Missense Mutation (SNP) | VAF 340/514 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PAPPA | c.3640G>C p.D1214H | Missense Mutation (SNP) | VAF 109/170 reads (64%) | SIFT tolerated (0.06); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- PCDH11X | c.2417C>A p.P806Q | Missense Mutation (SNP) | VAF 135/340 reads (40%) | SIFT tolerated (0.32); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- PGLYRP2 | c.214G>A p.G72R | Missense Mutation (SNP) | VAF 42/318 reads (13%) | SIFT tolerated (0.41); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PIK3C2G | c.1599C>G p.H533Q | Missense Mutation (SNP) | VAF 64/140 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- PIRT | c.133C>A p.P45T | Missense Mutation (SNP) | VAF 134/204 reads (66%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.651); called by muse, mutect2, varscan2
- PKD1L1 | c.2894_2895del p.E965Vfs*10 | Frame Shift Del (DEL) | VAF 190/570 reads (33%) | called by pindel, varscan2
- PKD2L1 | c.2104G>A p.V702I | Missense Mutation (SNP) | VAF 20/194 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- POLA2 | c.297-1G>T p.X99_splice | Splice Site (SNP) | VAF 140/382 reads (37%) | called by muse, mutect2, varscan2
- PPFIA4 | c.2237A>G p.K746R (on ENST00000447715; = p.K747R on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 233/627 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- PPP1R3A | c.2955_2973del p.G986Afs*2 | Frame Shift Del (DEL) | VAF 97/342 reads (28%) | called by mutect2, pindel, varscan2
- PPP6C | c.176A>C p.Y59S | Missense Mutation (SNP) | VAF 6/79 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.948); called by muse, mutect2
- PRAMEF4 | c.187T>A p.F63I | Missense Mutation (SNP) | VAF 850/2464 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- PTPRB | c.4649C>A p.A1550E | Missense Mutation (SNP) | VAF 150/460 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.411); called by muse, mutect2, varscan2
- PTX3 | c.619T>A p.F207I | Missense Mutation (SNP) | VAF 111/298 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- RBM18 | c.69A>C p.E23D | Missense Mutation (SNP) | VAF 29/202 reads (14%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2, varscan2
- RGL2 | c.411G>A p.M137I | Missense Mutation (SNP) | VAF 103/232 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- ROS1 | c.4394C>A p.T1465K | Missense Mutation (SNP) | VAF 167/363 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- RPL13 | c.518A>G p.E173G | Missense Mutation (SNP) | VAF 76/208 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- SENP1 | c.1494C>A p.F498L | Missense Mutation (SNP) | VAF 76/278 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- SLC8A3 | c.479T>A p.F160Y | Missense Mutation (SNP) | VAF 48/260 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SMYD1 | c.889C>T p.P297S | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.191); called by muse, mutect2, varscan2
- SOX9 | c.1301C>A p.P434H | Missense Mutation (SNP) | VAF 166/1097 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- SYNE2 | c.10388G>A p.W3463* | Nonsense Mutation (SNP) | VAF 76/421 reads (18%) | called by muse, mutect2, varscan2
- TDRD15 | c.4622G>C p.R1541T | Missense Mutation (SNP) | VAF 40/85 reads (47%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, mutect2, varscan2
- TENM2 | c.1098G>T p.K366N (on ENST00000518659 / NM_001122679.2; = p.K175N on NM_001080428.3) | Missense Mutation (SNP) | VAF 289/501 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- TENM3 | c.7905_7906del p.E2636Afs*100 | Frame Shift Del (DEL) | VAF 56/148 reads (38%) | called by pindel, varscan2
- THEM5 | c.353G>T p.R118M | Missense Mutation (SNP) | VAF 85/350 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); called by muse, mutect2, varscan2
- TIMM29 | c.249C>G p.F83L | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- TMC7 | c.1784G>T p.R595I | Missense Mutation (SNP) | VAF 144/406 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TNFRSF11A | c.332G>A p.R111H | Missense Mutation (SNP) | VAF 24/345 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.784); called by muse, mutect2
- TNFRSF19 | c.342C>A p.C114* | Nonsense Mutation (SNP) | VAF 99/145 reads (68%) | called by muse, mutect2, varscan2
- TNFSF13B | c.524G>C p.G175A | Missense Mutation (SNP) | VAF 52/179 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); called by muse, mutect2, varscan2
- TNS1 | c.3188A>G p.N1063S | Missense Mutation (SNP) | VAF 95/134 reads (71%) | SIFT tolerated (0.12); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- TRIM32 | c.1774G>A p.A592T | Missense Mutation (SNP) | VAF 189/303 reads (62%) | SIFT tolerated (0.23); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- TRIM49 | c.1110G>T p.K370N | Missense Mutation (SNP) | VAF 165/993 reads (17%) | SIFT tolerated (0.47); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TRIP4 | c.1129G>A p.G377R | Missense Mutation (SNP) | VAF 40/202 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- TSC2 | c.3815-8C>T | Splice Region (SNP) | VAF 370/580 reads (64%) | called by muse, mutect2, varscan2
- TTK | c.174G>T p.M58I | Missense Mutation (SNP) | VAF 42/186 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.03); called by muse, varscan2
- UBR4 | c.12358G>A p.D4120N | Missense Mutation (SNP) | VAF 64/82 reads (78%) | SIFT tolerated (0.41); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- UCK1 | c.530G>A p.G177E | Missense Mutation (SNP) | VAF 20/442 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- UGT2A1 | c.368A>G p.Q123R | Missense Mutation (SNP) | VAF 58/244 reads (24%) | SIFT tolerated (0.77); PolyPhen benign (0); called by muse, mutect2, varscan2
- USO1 | c.2584-1G>A p.X862_splice | Splice Site (SNP) | VAF 53/338 reads (16%) | called by muse, mutect2, varscan2
- VAMP7 | c.31G>T p.G11W | Missense Mutation (SNP) | VAF 42/184 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- VBP1 | c.255G>T p.L85F | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); called by muse, mutect2, varscan2
- WBP1L | c.92G>T p.G31V | Missense Mutation (SNP) | VAF 376/567 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- WNK2 | c.6515A>T p.K2172M (on ENST00000297954 / NM_001282394.1; = p.K2135M on NM_006648.3) | Missense Mutation (SNP) | VAF 403/614 reads (66%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- XRCC5 | c.1395G>C p.K465N | Missense Mutation (SNP) | VAF 70/188 reads (37%) | SIFT tolerated (0.29); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZDBF2 | c.3279A>T p.K1093N | Missense Mutation (SNP) | VAF 43/73 reads (59%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.561); called by muse, mutect2, varscan2
- ANK1 | c.5283G>A p.T1761= | Silent (SNP) | VAF 64/607 reads (11%) | catalogued as rs144122155; called by muse, mutect2, varscan2
- ARID5B | c.1395A>C p.A465= | Silent (SNP) | VAF 79/116 reads (68%) | called by muse, mutect2, varscan2
- ASPM | c.3348G>A p.L1116= | Silent (SNP) | VAF 108/229 reads (47%) | called by muse, mutect2, varscan2
- ATR | c.4260C>G p.A1420= | Silent (SNP) | VAF 153/460 reads (33%) | called by muse, mutect2, varscan2
- BNIP5 | c.1317C>T p.F439= | Silent (SNP) | VAF 383/1353 reads (28%) | called by muse, mutect2, varscan2
- C1orf185 | c.264G>A p.E88= | Silent (SNP) | VAF 50/93 reads (54%) | catalogued as rs1426278565; called by muse, mutect2, varscan2
- CACNA1C | c.1083C>T p.T361= | Silent (SNP) | VAF 280/625 reads (45%) | called by muse, mutect2, varscan2
- CASKIN1 | c.990C>T p.G330= | Silent (SNP) | VAF 154/245 reads (63%) | called by muse, mutect2, varscan2
- CCR6 | c.705G>T p.T235= | Silent (SNP) | VAF 152/321 reads (47%) | catalogued as rs775586288, COSV59473854; called by muse, mutect2, varscan2
- CDH12 | c.2148C>T p.F716= | Silent (SNP) | VAF 70/367 reads (19%) | catalogued as COSV66412000; called by muse, mutect2
- CDH6 | c.1785G>A p.G595= | Silent (SNP) | VAF 221/719 reads (31%) | catalogued as rs1289081425, COSV54070500; called by muse, mutect2, varscan2
- CLDN1 | c.186C>T p.I62= | Silent (SNP) | VAF 252/2122 reads (12%) | called by muse, varscan2
- CLDN1 | c.117C>T p.N39= | Silent (SNP) | VAF 502/4030 reads (12%) | catalogued as rs768443254; called by muse, varscan2
- CPS1 | c.642A>G p.K214= | Silent (SNP) | VAF 217/349 reads (62%) | called by muse, mutect2, varscan2
- DCDC2C | c.669C>A p.P223= | Silent (SNP) | VAF 66/142 reads (46%) | called by muse, mutect2, varscan2
- DDX25 | c.954G>A p.L318= | Silent (SNP) | VAF 22/706 reads (3%) | called by muse, mutect2
- DLG5 | c.604C>T p.L202= | Silent (SNP) | VAF 33/795 reads (4%) | called by muse, mutect2
- DNAH3 | c.10429C>A p.R3477= | Silent (SNP) | VAF 100/292 reads (34%) | called by muse, mutect2, varscan2
- DNAJC13 | c.2160T>C p.D720= | Silent (SNP) | VAF 34/818 reads (4%) | called by muse, mutect2
- DPP6 | c.1251C>T p.V417= (on ENST00000377770 / NM_001364500.2; = p.V355= on NM_001936.5) | Silent (SNP) | VAF 32/199 reads (16%) | called by muse, mutect2, varscan2
- DSCAML1 | c.1974G>A p.L658= (on ENST00000321322; = p.L598= on NM_020693.4) | Silent (SNP) | VAF 33/299 reads (11%) | catalogued as rs1389482067, COSV58403966; called by muse, mutect2, varscan2
- EXOSC6 | c.24C>T p.I8= | Silent (SNP) | VAF 103/311 reads (33%) | catalogued as rs543954936; called by muse, mutect2
- F11 | c.1059C>T p.N353= | Silent (SNP) | VAF 50/389 reads (13%) | catalogued as rs766026346, COSV53005100; called by muse, mutect2, varscan2
- FAM171B | c.528A>G p.L176= | Silent (SNP) | VAF 80/127 reads (63%) | called by muse, mutect2, varscan2
- FAM90A10P | c.1032G>A p.T344= | Silent (SNP) | VAF 534/1050 reads (51%) | catalogued as rs770741971; called by muse, mutect2, varscan2
- FLG2 | c.7083T>C p.Y2361= | Silent (SNP) | VAF 87/223 reads (39%) | called by muse, mutect2, varscan2
- FRMD7 | c.2019C>A p.P673= | Silent (SNP) | VAF 32/176 reads (18%) | called by muse, mutect2, varscan2
- GDPD2 | c.1356G>A p.K452= | Silent (SNP) | VAF 41/230 reads (18%) | called by muse, mutect2, varscan2
- GIMD1 | c.165C>G p.L55= | Silent (SNP) | VAF 179/398 reads (45%) | called by muse, mutect2, varscan2
- GPC6 | c.708C>A p.S236= | Silent (SNP) | VAF 69/237 reads (29%) | called by muse, mutect2, varscan2
- GULP1 | c.540T>C p.N180= | Silent (SNP) | VAF 52/90 reads (58%) | called by muse, mutect2, varscan2
- HELZ2 | c.1485G>T p.V495= | Silent (SNP) | VAF 192/451 reads (43%) | called by muse, mutect2, varscan2
- HEPH | c.1182C>A p.G394= (on ENST00000343002; = p.G127= on NM_014799.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 49/203 reads (24%) | called by muse, mutect2, varscan2
- IL5RA | c.147A>G p.Q49= | Silent (SNP) | VAF 46/128 reads (36%) | catalogued as rs1175668767; called by muse, mutect2, varscan2
- INCENP | c.1482C>T p.T494= | Silent (SNP) | VAF 126/392 reads (32%) | called by muse, mutect2, varscan2
- INPP5J | c.1734C>T p.I578= (on ENST00000331075 / NM_001284285.2; = p.I210= on NM_001002837.2) | Silent (SNP) | VAF 133/324 reads (41%) | called by muse, mutect2, varscan2
- KCND1 | c.639T>G p.S213= | Silent (SNP) | VAF 250/791 reads (32%) | catalogued as rs1557058538; called by muse, mutect2, varscan2
- KRTAP21-2 | c.219T>G p.L73= | Silent (SNP) | VAF 18/140 reads (13%) | called by mutect2, varscan2
- LIMA1 | c.570T>C p.Y190= | Silent (SNP) | VAF 73/170 reads (43%) | catalogued as COSV57966028; called by muse, mutect2, varscan2
- LRRC3 | c.525A>G p.S175= | Silent (SNP) | VAF 431/928 reads (46%) | called by muse, mutect2, varscan2
- LRRTM4 | c.1689G>T p.L563= | Silent (SNP) | VAF 410/1069 reads (38%) | called by muse, mutect2, varscan2
- LY6G5C | c.264G>A p.P88= | Silent (SNP) | VAF 168/592 reads (28%) | called by muse, varscan2
- MAGEH1 | c.183C>A p.A61= | Silent (SNP) | VAF 121/369 reads (33%) | catalogued as COSV61678742; called by muse, mutect2, varscan2
- MALRD1 | c.3084T>C p.N1028= | Silent (SNP) | VAF 10/65 reads (15%) | called by mutect2, varscan2
- MLIP | c.624C>G p.T208= | Silent (SNP) | VAF 57/315 reads (18%) | called by muse, mutect2, varscan2
- MON2 | c.2823T>G p.P941= | Silent (SNP) | VAF 13/146 reads (9%) | called by muse, mutect2
- MSLNL | c.1419C>T p.D473= | Silent (SNP) | VAF 17/211 reads (8%) | catalogued as rs751673243; called by muse, mutect2
- MYH6 | c.2961G>T p.L987= | Silent (SNP) | VAF 217/433 reads (50%) | catalogued as rs891595641; called by muse, mutect2, varscan2
- NOVA2 | c.963C>A p.A321= | Silent (SNP) | VAF 137/205 reads (67%) | called by muse, mutect2, varscan2
- NPIPB15 | c.99T>C p.R33= | Silent (SNP) | VAF 72/849 reads (8%) | called by muse, mutect2
- OR2M5 | c.252C>T p.N84= | Silent (SNP) | VAF 43/235 reads (18%) | catalogued as COSV63546498; called by muse, varscan2
- OR2T34 | c.219C>G p.L73= | Silent (SNP) | VAF 88/514 reads (17%) | called by muse, mutect2, varscan2
- OR4C3 | c.108G>A p.T36= | Silent (SNP) | VAF 44/115 reads (38%) | catalogued as rs78490540; called by muse, mutect2, varscan2
- OR5AR1 | c.678C>A p.I226= | Silent (SNP) | VAF 108/229 reads (47%) | catalogued as COSV100265527; called by muse, mutect2, varscan2
- OR9Q2 | c.252G>T p.V84= | Silent (SNP) | VAF 192/559 reads (34%) | called by muse, mutect2, varscan2
- PIDD1 | c.633T>G p.P211= | Silent (SNP) | VAF 127/186 reads (68%) | called by muse, mutect2, varscan2
- PIEZO1 | c.2283G>A p.E761= | Silent (SNP) | VAF 65/139 reads (47%) | catalogued as rs983934342; called by muse, mutect2, varscan2
- PLVAP | c.501G>C p.T167= | Silent (SNP) | VAF 123/248 reads (50%) | called by muse, mutect2, varscan2
- POU4F2 | c.15C>A p.S5= | Silent (SNP) | VAF 505/861 reads (59%) | called by muse, mutect2, varscan2
- PRDM5 | c.1470C>A p.I490= | Silent (SNP) | VAF 54/471 reads (11%) | called by muse, mutect2, varscan2
- SERPINA4 | c.225C>A p.I75= | Silent (SNP) | VAF 89/518 reads (17%) | called by muse, mutect2, varscan2
- SHANK1 | c.1194G>T p.L398= | Silent (SNP) | VAF 135/255 reads (53%) | called by muse, mutect2, varscan2
- SKA1 | c.246A>G p.K82= | Silent (SNP) | VAF 86/294 reads (29%) | called by muse, mutect2, varscan2
- SKIV2L | c.1161A>T p.V387= | Silent (SNP) | VAF 141/409 reads (34%) | called by muse, mutect2, varscan2
- SMCO3 | c.531T>A p.R177= | Silent (SNP) | VAF 146/325 reads (45%) | called by muse, mutect2, varscan2
- SORCS1 | c.3183C>A p.I1061= | Silent (SNP) | VAF 157/241 reads (65%) | catalogued as rs1365523432; called by muse, mutect2, varscan2
- STXBP5 | c.2769A>G p.A923= (on ENST00000321680 / NM_001127715.2; = p.A887= on NM_139244.4) | Silent (SNP) | VAF 50/250 reads (20%) | called by muse, mutect2, varscan2
- SYNPO2 | c.924G>A p.V308= | Silent (SNP) | VAF 149/663 reads (22%) | called by muse, mutect2, varscan2
- TANC2 | c.4497G>A p.R1499= | Silent (SNP) | VAF 200/452 reads (44%) | called by muse, mutect2, varscan2
- TBXT | c.351G>A p.P117= | Silent (SNP) | VAF 476/997 reads (48%) | catalogued as COSV51615910; called by muse, mutect2, varscan2
- TDRD6 | c.327A>C p.A109= | Silent (SNP) | VAF 199/425 reads (47%) | called by muse, mutect2, varscan2
- TEX13C | c.831A>T p.T277= | Silent (SNP) | VAF 309/582 reads (53%) | called by muse, mutect2, varscan2
- UBALD1 | c.387G>A p.S129= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as rs1186295720; called by muse, mutect2
- ZC3H12B | c.1713C>T p.D571= | Silent (SNP) | VAF 381/1784 reads (21%) | called by mutect2, varscan2
- ZDBF2 | c.4083T>A p.S1361= | Silent (SNP) | VAF 90/157 reads (57%) | called by muse, mutect2, varscan2
- ZFHX4 | c.5733G>A p.A1911= | Silent (SNP) | VAF 241/947 reads (25%) | catalogued as rs377346853; called by muse, mutect2, varscan2
- ZNF430 | c.1473C>G p.G491= | Silent (SNP) | VAF 87/268 reads (32%) | catalogued as COSV55112019, COSV55112256; called by muse, mutect2, varscan2
- ZNF804B | c.756C>A p.P252= | Silent (SNP) | VAF 33/157 reads (21%) | catalogued as COSV100306042, COSV60857174; called by muse, mutect2, varscan2
- ABCC13 | n.389T>G | RNA (SNP) | VAF 35/115 reads (30%) | called by muse, mutect2, varscan2
- ABCG8 | c.-22_-18dup | 5'UTR (INS) | VAF 65/296 reads (22%) | called by mutect2, pindel, varscan2
- ACTR3BP2 | n.889C>G | RNA (SNP) | VAF 49/336 reads (15%) | called by muse, mutect2, varscan2
- ANKRD36C | c.2653+1685A>G | Intron (SNP) | VAF 14/260 reads (5%) | called by muse, mutect2
- ANO1 | c.109-2183C>T | Intron (SNP) | VAF 202/494 reads (41%) | catalogued as rs1335209068; called by muse, mutect2, varscan2
- ATXN7L1 | c.2472+46G>C | Intron (SNP) | VAF 70/314 reads (22%) | called by muse, mutect2, varscan2
- BTN2A3P | n.1129G>A | RNA (SNP) | VAF 39/175 reads (22%) | called by muse, mutect2, varscan2
- CCSER1 | c.2217+233110C>A | Intron (SNP) | VAF 5/26 reads (19%) | called by muse, mutect2, varscan2
- CHCHD10 | c.*29C>G | 3'UTR (SNP) | VAF 76/706 reads (11%) | called by muse, mutect2, varscan2
- DDX60 | c.-46C>G | 5'UTR (SNP) | VAF 22/76 reads (29%) | called by muse, mutect2, varscan2
- DENND2D | chr1:111204357 C>T | 5'Flank (SNP) | VAF 22/77 reads (29%) | called by muse, mutect2, varscan2
- FER1L4 | n.2732G>T | RNA (SNP) | VAF 87/177 reads (49%) | called by muse, mutect2, varscan2
- GYPB | c.*37C>G | 3'UTR (SNP) | VAF 20/160 reads (13%) | called by muse, mutect2, varscan2
- HERC2P3 | n.874C>A | RNA (SNP) | VAF 450/2291 reads (20%) | called by muse, mutect2, varscan2
- LINC00671 | n.428G>A | RNA (SNP) | VAF 132/174 reads (76%) | called by muse, mutect2, varscan2
- LINC01098 | n.584A>T | RNA (SNP) | VAF 9/41 reads (22%) | called by muse, mutect2, varscan2
- MAGEA5 | n.13C>A | RNA (SNP) | VAF 33/169 reads (20%) | called by muse, mutect2, varscan2
- MAOA | chrX:43656297 G>C | 5'Flank (SNP) | VAF 184/498 reads (37%) | called by muse, mutect2, varscan2
- MEF2A | c.-77T>C | 5'UTR (SNP) | VAF 74/169 reads (44%) | called by muse, mutect2, varscan2
- MEF2A | c.-76G>T | 5'UTR (SNP) | VAF 74/169 reads (44%) | called by muse, mutect2, varscan2
- MS4A5 | c.*6A>G | 3'UTR (SNP) | VAF 96/240 reads (40%) | called by muse, mutect2, varscan2
- PARG | c.-119C>A | 5'UTR (SNP) | VAF 14/43 reads (33%) | called by muse, mutect2, varscan2
- PKLR | c.*31C>A | 3'UTR (SNP) | VAF 38/335 reads (11%) | catalogued as COSV100713066; called by muse, mutect2
- PMM2 | chr16:8797836 T>A | 5'Flank (SNP) | VAF 262/794 reads (33%) | called by muse, mutect2, varscan2
- POU4F3 | c.*10G>C | 3'UTR (SNP) | VAF 399/669 reads (60%) | called by muse, mutect2, varscan2
- PRR12 | c.52-79C>G | Intron (SNP) | VAF 27/398 reads (7%) | catalogued as COSV69820188; called by muse, mutect2
- REXO1L1P | n.1511C>T | RNA (SNP) | VAF 121/4302 reads (3%) | catalogued as rs766693941; called by muse, mutect2
- SIAH1 | chr16:48365405 T>C | 5'Flank (SNP) | VAF 127/389 reads (33%) | called by muse, mutect2, varscan2
- SNX32 | c.141+13G>C | Intron (SNP) | VAF 54/558 reads (10%) | called by muse, mutect2
- SORBS1 | c.2128+922G>A | Intron (SNP) | VAF 436/615 reads (71%) | catalogued as rs987927118; called by muse, mutect2, varscan2
- ST8SIA6 | c.*2178T>A | 3'UTR (SNP) | VAF 32/261 reads (12%) | called by muse, mutect2, varscan2
- TAP2 | chr6:32822239 A>T | 3'Flank (SNP) | VAF 107/245 reads (44%) | called by muse, mutect2, varscan2
- TMEM26 | c.682+469A>T | Intron (SNP) | VAF 10/126 reads (8%) | called by muse, mutect2
- UBE2N | c.277+18C>G | Intron (SNP) | VAF 86/216 reads (40%) | called by muse, mutect2, varscan2
